Somatic mutation profile of tumor specimen C3N-03754-01 (aliquot CPT0246810006) from CPTAC case C3N-03754, project CPTAC-3 (Pancreas — Ductal and Lobular Neoplasms). Sex at birth: male; Vital status: Dead; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Pancreas, NOS; AJCC pathologic stage: Stage III; Tumor grade: G2; Age at diagnosis: 44.5 years (16,266 days).
Specimen C3N-03754-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Pancreas; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 2daad52b-8749-4899-a57c-27aa06b1f19c.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3N-03754-31 (Blood Derived Normal), aliquot CPT0246830002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/9283fd30-9532-4b42-b253-4b3036edb057

The open-access MAF lists 36 somatic variants for this specimen: 24 protein-altering or splice-affecting, 11 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 22, Silent 11, Nonsense Mutation 2, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BAP1 | c.1153C>T p.R385* | Nonsense Mutation (SNP) | VAF 56/339 reads (17%) | catalogued as rs1553645164, CM123455, COSV56230370; ClinVar: pathogenic; called by muse, mutect2, varscan2
- KRAS | c.35G>A p.G12D | Missense Mutation (SNP) | VAF 29/177 reads (16%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.303); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.517G>T p.V173L | Missense Mutation (SNP) | VAF 113/387 reads (29%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen possibly damaging (0.827); catalogued as rs876660754, CM070299, COSV52676535, COSV52677795, COSV52695723, COSV52823354; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ABCB1 | c.1789G>A p.V597I | Missense Mutation (SNP) | VAF 16/182 reads (9%) | SIFT tolerated (0.21); PolyPhen benign (0.005); catalogued as rs199931362, COSV55952252; called by muse, mutect2
- AP3B1 | c.1928C>T p.A643V | Missense Mutation (SNP) | VAF 30/244 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0.266); catalogued as rs769622520; called by muse, varscan2
- CD5 | c.174G>T p.M58I | Missense Mutation (SNP) | VAF 65/342 reads (19%) | SIFT tolerated (0.1); PolyPhen benign (0.08); catalogued as COSV61718396; called by muse, mutect2, varscan2
- CDKN2A | c.131dup p.Y44* | Nonsense Mutation (INS) | VAF 37/272 reads (14%) | catalogued as rs730881673; called by mutect2, pindel, varscan2
- DGKZ | c.629G>T p.G210V | Missense Mutation (SNP) | VAF 45/291 reads (15%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.043); catalogued as rs1170491363; called by muse, mutect2, varscan2
- HIF3A | c.1567C>T p.R523C (on ENST00000377670 / NM_152795.4; = p.R454C on NM_022462.4) | Missense Mutation (SNP) | VAF 24/228 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.926); catalogued as rs955256023, COSV52198975; called by muse, mutect2, varscan2
- HRH3 | c.952C>T p.R318C | Missense Mutation (SNP) | VAF 8/57 reads (14%) | SIFT tolerated (0.15); PolyPhen benign (0.007); catalogued as rs201799413, COSV100420420; called by muse, mutect2
- HYDIN | c.3278G>T p.G1093V | Missense Mutation (SNP) | VAF 14/184 reads (8%) | SIFT tolerated (0.45); PolyPhen benign (0.219); catalogued as COSV66833078, COSV66833525; called by muse, mutect2
- OR5L2 | c.349G>A p.V117M | Missense Mutation (SNP) | VAF 43/213 reads (20%) | SIFT deleterious (0.02); PolyPhen benign (0.084); catalogued as rs202214388, COSV65723601, COSV65724678; called by muse, mutect2, varscan2
- PCDH15 | c.854C>T p.A285V | Missense Mutation (SNP) | VAF 26/301 reads (9%) | SIFT tolerated (0.13); PolyPhen benign (0.003); catalogued as rs768148484, COSV57374240; called by muse, mutect2
- PCDHA6 | c.1936C>T p.R646W | Missense Mutation (SNP) | VAF 70/498 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.901); catalogued as rs782267488; called by muse, mutect2, varscan2
- PRKAB1 | c.124G>C p.E42Q | Missense Mutation (SNP) | VAF 71/388 reads (18%) | SIFT tolerated (0.09); PolyPhen benign (0.183); catalogued as COSV57554979; called by muse, mutect2
- RABEP2 | c.1667A>G p.D556G | Missense Mutation (SNP) | VAF 30/205 reads (15%) | SIFT deleterious (0.02); PolyPhen benign (0.106); catalogued as rs547755398; called by muse, mutect2, varscan2
- TIMELESS | c.1987C>G p.R663G | Missense Mutation (SNP) | VAF 48/185 reads (26%) | SIFT tolerated (0.3); PolyPhen benign (0); catalogued as rs745896818; called by muse, mutect2, varscan2
- IZUMO1R | c.318G>C p.W106C | Missense Mutation (SNP) | VAF 30/394 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- LTN1 | c.3727G>A p.E1243K | Missense Mutation (SNP) | VAF 11/46 reads (24%) | SIFT deleterious (0.04); PolyPhen benign (0.057); called by muse, mutect2, varscan2
- PAPOLA | c.1075T>C p.S359P | Missense Mutation (SNP) | VAF 4/52 reads (8%) | SIFT tolerated (0.2); PolyPhen benign (0.026); called by muse, mutect2
- PHYHIPL | c.1118G>T p.S373I | Missense Mutation (SNP) | VAF 9/35 reads (26%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.534); called by muse, mutect2
- PRKAB1 | c.126A>C p.E42D | Missense Mutation (SNP) | VAF 71/389 reads (18%) | SIFT tolerated (0.88); PolyPhen benign (0.003); called by muse, mutect2
- PRUNE2 | c.9040C>A p.P3014T | Missense Mutation (SNP) | VAF 8/54 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- RPGRIP1L | c.545A>T p.D182V | Missense Mutation (SNP) | VAF 15/133 reads (11%) | SIFT deleterious (0.02); PolyPhen benign (0.118); called by muse, mutect2, varscan2
- ANKHD1-EIF4EBP3 | c.48G>T p.L16= | Silent (SNP) | VAF 11/73 reads (15%) | called by muse, mutect2, varscan2
- CORIN | c.112C>T p.L38= | Silent (SNP) | VAF 30/157 reads (19%) | called by muse, mutect2, varscan2
- INSR | c.588C>T p.C196= | Silent (SNP) | VAF 36/186 reads (19%) | called by muse, mutect2, varscan2
- NRK | c.2226G>A p.L742= | Silent (SNP) | VAF 14/55 reads (25%) | called by muse, mutect2, varscan2
- OPLAH | c.2763G>A p.S921= | Silent (SNP) | VAF 32/202 reads (16%) | catalogued as rs782103109; called by muse, mutect2, varscan2
- PRR23A | c.468C>T p.Y156= | Silent (SNP) | VAF 109/560 reads (19%) | catalogued as rs749352615, COSV67214839; called by muse, mutect2, varscan2
- PTPRS | c.1437C>T p.N479= | Silent (SNP) | VAF 49/254 reads (19%) | catalogued as rs1002891578, COSV53626191; called by muse, mutect2, varscan2
- SCN9A | c.3567T>A p.V1189= (on ENST00000303354; = p.V1178= on NM_002977.3) | Silent (SNP) | VAF 7/51 reads (14%) | called by muse, mutect2, varscan2
- SLC17A7 | c.1371G>A p.G457= | Silent (SNP) | VAF 20/92 reads (22%) | catalogued as rs776117731; called by muse, mutect2, varscan2
- SLC30A8 | c.472C>T p.L158= | Silent (SNP) | VAF 31/212 reads (15%) | called by muse, mutect2, varscan2
- THUMPD1 | c.537T>C p.Y179= | Silent (SNP) | VAF 21/106 reads (20%) | called by muse, mutect2, varscan2
- NKAIN4 | c.618-234G>A | Intron (SNP) | VAF 26/218 reads (12%) | catalogued as rs906312161; called by muse, mutect2
